Somatic mutation profile of tumor specimen TCGA-B0-5712-01A (aliquot TCGA-B0-5712-01A-11D-1669-08) from TCGA case TCGA-B0-5712, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.4 years (24,988 days).
Specimen TCGA-B0-5712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f845229-4bca-419f-ab25-25f63f05ee74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5712-11A (Solid Tissue Normal), aliquot TCGA-B0-5712-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/878201b4-3164-49cd-a775-1589853e71fb

The open-access MAF lists 110 somatic variants for this specimen: 87 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 18, Frame Shift Del 13, Nonsense Mutation 7, Frame Shift Ins 4, Intron 3, Splice Region 3, Splice Site 3, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.2581A>G p.K861E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV64600325; called by muse, mutect2, varscan2
- AKAP9 | c.9432A>G p.E3144= (on ENST00000359028; = p.E3120= on NM_005751.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/53 reads (34%) | catalogued as rs1332498946, COSV100661922; called by muse, mutect2
- ARHGAP35 | c.2102T>C p.I701T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV68329714; called by muse, mutect2, varscan2
- ARID5B | c.2149A>G p.I717V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.1); catalogued as rs764739348, COSV54415898; called by muse, mutect2, varscan2
- ARMC4 | c.2909G>C p.R970P | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV59458683, COSV59464830; called by muse, mutect2, varscan2
- ATP6V0A2 | c.691G>C p.G231R | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57748043; called by muse, mutect2, varscan2
- C2CD6 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as COSV53792240; called by muse, mutect2, varscan2
- C6 | c.689A>C p.Y230S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV54706787; called by muse, mutect2
- CALHM1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV53294666; called by muse, varscan2
- CDR1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 114/328 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.069); catalogued as COSV65163943; called by muse, mutect2, varscan2
- CHID1 | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.465); catalogued as COSV60258113; called by muse, mutect2, varscan2
- CHRNA4 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as rs200810080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIITA | c.937+2T>A p.X313_splice | Splice Site (SNP) | VAF 35/114 reads (31%) | catalogued as COSV60854948; called by muse, mutect2, varscan2
- CNDP1 | c.1168-2A>G p.X390_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV62593348; called by muse, varscan2
- CNDP2 | c.749T>A p.L250* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV60839304; called by muse, mutect2, varscan2
- COL1A2 | c.133-2A>T p.X45_splice | Splice Site (SNP) | VAF 47/148 reads (32%) | catalogued as COSV51954526; called by muse, mutect2, varscan2
- COL6A3 | c.1925T>G p.F642C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55082609; called by muse, mutect2, varscan2
- COX19 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 137/454 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59937367; called by muse, mutect2, varscan2
- CSRNP2 | c.212T>A p.V71E | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57333902; called by muse, mutect2, varscan2
- DENND5A | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs375955901, COSV60232054, COSV60234949; called by muse, mutect2, varscan2
- DIAPH1 | c.3663C>A p.A1221= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52746210; called by muse, mutect2, varscan2
- DNAH2 | c.10153G>A p.V3385I | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs758341170, COSV66717463; called by muse, mutect2
- DNMT3B | c.1243C>A p.Q415K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52415833; called by muse, mutect2, varscan2
- DPEP1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370798757; called by muse, mutect2
- DST | c.4952G>C p.S1651T | Missense Mutation (SNP) | VAF 100/363 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99751243; called by muse, mutect2, varscan2
- DYNC2I1 | c.1694T>A p.V565E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV68103930; called by muse, mutect2
- EEA1 | c.2806A>G p.M936V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757762798, COSV59283462; called by muse, varscan2
- EFNB1 | c.790A>T p.K264* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV52661248; called by muse, mutect2, varscan2
- EIF5AL1 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV101592836, COSV73122947; called by muse, mutect2, varscan2
- HSPA8 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV57083026; called by muse, mutect2, varscan2
- IRF7 | c.557C>A p.P186H (on ENST00000397566; = p.P173H on NM_001572.5) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV52752495; called by muse, mutect2, varscan2
- KIF1A | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV57484488, COSV57486873; called by muse, mutect2, varscan2
- KLHL13 | c.1288A>G p.K430E | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV53245590; called by muse, mutect2, varscan2
- LRRK2 | c.7105A>G p.N2369D | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV54146912; called by muse, mutect2, varscan2
- MAP3K1 | c.4316T>G p.I1439S | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV68122400; called by muse, mutect2, varscan2
- MAP3K11 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58418727; called by muse, mutect2, varscan2
- MAPT | c.2164C>T p.H722Y (on ENST00000262410 / NM_001377265.1; = p.H330Y on NM_005910.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52238016; called by muse, mutect2, varscan2
- MTA3 | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV68133113; called by muse, mutect2, varscan2
- MTOR | c.7264G>A p.V2422I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV63869160; called by muse, mutect2, varscan2
- MUC16 | c.11327T>G p.L3776W | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV67452241, COSV67483605; called by muse, mutect2
- MYL10 | c.351C>A p.G117= | Splice Region (SNP) | VAF 15/42 reads (36%) | catalogued as COSV56207394; called by muse, mutect2, varscan2
- MYO7A | c.4465G>A p.V1489I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs1265094428, COSV68683839; called by muse, mutect2, varscan2
- MYRF | c.2956C>T p.R986* (on ENST00000278836 / NM_001127392.3; = p.R951* on NM_013279.4) | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV53886721; called by muse, mutect2, varscan2
- NEURL4 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59757135; called by muse, mutect2, varscan2
- NPR1 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64140507; called by muse, mutect2, varscan2
- NUDT21 | c.388G>C p.G130R | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55859573; called by muse, mutect2, varscan2
- OR2J2 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1562640643, COSV65847822; called by muse, mutect2, varscan2
- PDZRN4 | c.3057G>C p.K1019N (on ENST00000402685 / NM_001164595.2; = p.K761N on NM_013377.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54194992; called by muse, mutect2, varscan2
- POTEF | c.2744A>C p.K915T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100664590; called by muse, mutect2
- RBM22 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as COSV52270799; called by muse, mutect2, varscan2
- RGS18 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201783745, COSV66507439; called by muse, mutect2, varscan2
- RPA1 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54607724; called by muse, mutect2
- RPA1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV54607736; called by muse, mutect2
- RTN1 | c.2230G>T p.A744S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50719714; called by muse, mutect2, varscan2
- SELL | c.592G>T p.G198W (on ENST00000650983; = p.G185W on NM_000655.5) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52550498; called by muse, mutect2
- SEMA6C | c.1232A>T p.H411L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as rs778906133, COSV59000732; called by muse, mutect2, varscan2
- SLC22A9 | c.1651A>G p.T551A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773334026, COSV54166239; called by muse, mutect2, varscan2
- SUPT6H | c.87A>C p.K29N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.137); catalogued as COSV58925300; called by muse, mutect2, varscan2
- SYNE1 | c.20236T>G p.L6746V (on ENST00000367255 / NM_182961.4; = p.L6675V on NM_033071.3) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54928265; called by muse, mutect2, varscan2
- TBXAS1 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV54942094; called by muse, mutect2, varscan2
- TENM1 | c.6987C>A p.S2329R | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64427114; called by muse, mutect2, varscan2
- THOP1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs200973060, COSV57017980; called by muse, mutect2, varscan2
- TKFC | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV67523341; called by muse, mutect2, varscan2
- TMED2 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV51628781; called by muse, mutect2, varscan2
- TRMT13 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV61582774; called by muse, mutect2, varscan2
- TUBGCP3 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV56184939; called by muse, mutect2, varscan2
- WDR5 | c.399T>G p.F133L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV62272605; called by muse, mutect2, varscan2
- YLPM1 | c.761dup p.G255Wfs*3 | Frame Shift Ins (INS) | VAF 20/35 reads (57%) | catalogued as rs760065689; called by mutect2, varscan2
- ZDHHC16 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV59134190; called by muse, mutect2, varscan2
- ZNF692 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs777208703, COSV60658875; called by muse, mutect2, varscan2
- DUSP12 | c.579del p.E193Dfs*21 | Frame Shift Del (DEL) | VAF 31/125 reads (25%) | called by mutect2, pindel, varscan2
- IL20RA | c.1378del p.L460Wfs*114 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- INTS4 | c.626del p.P209Hfs*8 | Frame Shift Del (DEL) | VAF 71/247 reads (29%) | called by mutect2, pindel, varscan2
- MAX | c.199del p.A67Pfs*103 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- MCTP1 | c.2118del p.V707Lfs*18 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | called by mutect2, pindel, varscan2
- MCTP2 | c.1808del p.N603Ifs*5 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1548_1549del p.N517Hfs*15 | Frame Shift Del (DEL) | VAF 27/56 reads (48%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.1181del p.T394Nfs*26 | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | called by mutect2, pindel, varscan2
- REPS2 | c.1224dup p.D409Rfs*4 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- SLC23A1 | c.1723del p.S575Qfs*27 | Frame Shift Del (DEL) | VAF 141/345 reads (41%) | called by mutect2, pindel, varscan2
- SSH2 | c.220dup p.Q74Pfs*40 | Frame Shift Ins (INS) | VAF 29/101 reads (29%) | called by mutect2, pindel, varscan2
- STAG2 | c.2250_2260del p.E750Dfs*31 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- TBC1D9B | c.3186del p.E1063Rfs*146 (on ENST00000356834 / NM_198868.3; = p.E1046Rfs*146 on NM_015043.4) | Frame Shift Del (DEL) | VAF 42/99 reads (42%) | called by mutect2, pindel, varscan2
- TFRC | c.860_862dup p.K287_F288ins* | Nonsense Mutation (INS) | VAF 55/86 reads (64%) | called by mutect2, pindel, varscan2
- THOC2 | c.4336_4345dup p.K1449Tfs*6 | Frame Shift Ins (INS) | VAF 30/135 reads (22%) | called by mutect2, varscan2
- TNS2 | c.1471del p.R491Gfs*29 (on ENST00000314250 / NM_170754.4; = p.R501Gfs*29 on NM_015319.2) | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- ZAN | c.3215del p.E1072Gfs*125 | Frame Shift Del (DEL) | VAF 58/190 reads (31%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.3891C>A p.V1297= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV53237745; called by muse, mutect2, varscan2
- ASB1 | c.810G>A p.S270= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs759586107, COSV52826507, COSV99223349; called by muse, mutect2, varscan2
- BCL9 | c.2874C>T p.S958= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV52341950; called by muse, mutect2, varscan2
- C11orf58 | c.246T>A p.S82= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV57178215; called by muse, mutect2, varscan2
- CNKSR2 | c.750A>C p.A250= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV54251100; called by muse, mutect2, varscan2
- CNTNAP5 | c.3108C>G p.S1036= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV70477366; called by muse, mutect2, varscan2
- CUBN | c.396C>T p.D132= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV64701297; called by muse, mutect2, varscan2
- ERCC6L | c.1032A>G p.R344= | Silent (SNP) | VAF 52/251 reads (21%) | catalogued as COSV57819761; called by muse, mutect2, varscan2
- HTATIP2 | c.489T>C p.S163= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV70041070; called by muse, mutect2, varscan2
- KPNB1 | c.1354C>T p.L452= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as rs1030266702, COSV51595593; called by muse, mutect2, varscan2
- RARG | c.150C>G p.G50= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs1209383985, COSV59531927; called by muse, mutect2, varscan2
- RPAP1 | c.834G>A p.E278= | Silent (SNP) | VAF 97/279 reads (35%) | catalogued as COSV58537510; called by muse, mutect2, varscan2
- SEPHS2 | c.1290C>A p.A430= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV72100719; called by muse, mutect2, varscan2
- SERTAD4 | c.396A>C p.I132= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV65398925; called by muse, mutect2, varscan2
- TTI1 | c.63C>A p.L21= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as COSV65060806; called by muse, mutect2, varscan2
- TTN | c.50178C>A p.I16726= (on ENST00000591111; = p.I9302= on NM_003319.4) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV59932396; called by muse, mutect2, varscan2
- TUBA1C | c.1122T>C p.A374= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV56509664; called by muse, mutect2, varscan2
- ZNF318 | c.3030C>T p.S1010= | Silent (SNP) | VAF 86/290 reads (30%) | catalogued as COSV58930873; called by muse, varscan2
- ADAM20 | c.-14A>C | 5'UTR (SNP) | VAF 43/105 reads (41%) | catalogued as COSV56454310; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 4/44 reads (9%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- AMMECR1 | c.585-8402G>A | Intron (SNP) | VAF 29/109 reads (27%) | catalogued as COSV99466282; called by muse, mutect2, varscan2
- PDZD2 | c.8219-168T>C | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99223742; called by muse, mutect2, varscan2
- PRICKLE2 | c.*2A>G | 3'UTR (SNP) | VAF 83/137 reads (61%) | catalogued as COSV99896646; called by muse, mutect2, varscan2
